Somatic mutation profile of tumor specimen MP2PRT-PAPZAK-TMP1-A (aliquot MP2PRT-PAPZAK-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZAK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,197 days).
Specimen MP2PRT-PAPZAK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78a2aaaf-c6f5-40dd-b72f-84264c6bd497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZAK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZAK-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/639ce00f-fbb3-4147-88d4-dea9d71c792b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.2188C>T p.R730W (on ENST00000622464; = p.R766W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/415 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776910050, COSV68243216; called by muse, mutect2, varscan2
- APBA2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 251/542 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376193947; called by muse, mutect2, varscan2
- OR8B12 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 86/508 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs148702196; called by muse, mutect2, varscan2
- SIX5 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 161/638 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs758153599; called by muse, mutect2, varscan2
- DEF6 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 102/655 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAPPA | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 285/554 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DNAH7 | c.279G>A p.K93= | Silent (SNP) | VAF 74/348 reads (21%) | called by muse, mutect2, varscan2
- RBBP8NL | c.702C>T p.A234= | Silent (SNP) | VAF 23/829 reads (3%) | catalogued as rs1249862247; called by muse, mutect2
